TCGA case TCGA-OR-A5KZ — Adrenocortical Carcinoma (TCGA-ACC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Adrenal gland; Tissue source site: University of Michigan. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/99f86b57-3894-45c5-bfbe-c757c69a3050

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Germany; Age at index: 42 years; Vital status: Dead; Days to death: 125 days.

Diagnoses (3)
1. Adrenal cortical carcinoma (the primary disease): ICD-O-3 morphology code: 8370/3; ICD-10 code: C74.0; Tissue or organ of origin: Cortex of adrenal gland; Site of resection or biopsy: Adrenal gland, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 42.7 years (15,594 days); Year of diagnosis: 2012; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: RX; Ensat clinical m: M0; Ensat pathologic n: N0; Ensat pathologic stage: Stage II; Ensat pathologic t: T2; Weiss assessment findings: Cytoplasm presence <= to 25% / Diffuse Architecture / Invasion of Tumor Capsule / Mitotic Rate > 5/50 HPF / Necrosis / Nuclear Grade III or IV / Sinusoid Invasion / Venous Invasion; Weiss assessment score: 8.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Mitotane; Treatment intent type: Adjuvant; Treatment outcome: Progressive Disease; Therapeutic target level: >14 mg/L.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Progressive Disease.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Recurrence of diagnosis 1 (Adrenal cortical carcinoma), site: Abdomen, NOS. Age at diagnosis: 42.8 years (15,630 days); Days to diagnosis: 36 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Radiation Therapy, NOS, for recurrent disease; Surgery, NOS, for recurrent disease.
3. Metastasis of diagnosis 1 (Adrenal cortical carcinoma), site: Bone, NOS. Age at diagnosis: 42.8 years (15,630 days); Days to diagnosis: 36 days; Prior treatment: Yes.

Follow-up (5 entries)
- Day 36 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Abdomen, NOS; Days to recurrence: 36 days; Evidence of recurrence type: Convincing Image Source; Histologic progression: No.
- Day 36 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Bone, NOS; Days to progression: 36 days.
- Day 125 (within 3 months of surgery): Disease response: Persistent Locoregional Disease.
- Days to follow up: 125 days; Disease response: With Tumor.
- Imaging type: CT Scan; Imaging findings: Normal; Timepoint: Preoperative.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Risk factor method of diagnosis: Both Clinical and Biochemical Assessments; Risk factors: Cortisol Excess.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-OR-A5KZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT; Initial weight: 120 mg.
  Slide TCGA-OR-A5KZ-01A-01-TSA: Section location: Top; Percent tumor cells: 81; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 19; Percent stromal cells: 0; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-OR-A5KZ-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor; Pharmaceutical treatment mitotane indicator: Yes; Clinical status within 3 mths surgery: Persistent locoregional disease.
- Primary pathology: Submitted tumor site: Adrenal; Histologic diagnosis: Adrenocortical carcinoma- Usual Type; Ct scan preop results: Yes.
- Primary pathology, Weiss assessment report, Weiss assessment categories: Nuclear grade III IV: Nuclear Grade III or IV Present; Mitotic rate: Mitotic Rate > 5/50 HPF Present; Atypical mitotic figures: Atypical Mitotic Figures Absent; Cytoplasm presence less than equal 25 percent: Cytoplasm presence <= 25% Present; Diffuse architecture: Diffuse Architecture Present; Necrosis: Necrosis Present; Weiss venous invasion: Venous Invasion Present; Sinusoid invasion: Sinusoid Invasion Present; Invasion of tumor capsule: Invasion of Tumor Capsule Present.
- Primary pathology, Excess adrenal hormone history types: History adrenal hormone excess: Cortisol.
- Primary pathology, Germline genotype testing report: Molecular studies others performed: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 125 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 125 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 36 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-OR-A5KZ-01A-11D-A29H-01): tumor purity 0.95, ploidy 2.37, whole-genome doublings 1.
